Somatic mutation profile of tumor specimen TCGA-QQ-A5V9-01A (aliquot TCGA-QQ-A5V9-01A-11D-A32I-09) from TCGA case TCGA-QQ-A5V9, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Age at diagnosis: 76.6 years (27,977 days).
Specimen TCGA-QQ-A5V9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 210862e8-c194-4062-b842-27cde53d99d9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QQ-A5V9-11A (Solid Tissue Normal), aliquot TCGA-QQ-A5V9-11A-31D-A32I-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e2bf9408-210b-4a49-8296-f889a835e1ee

The open-access MAF lists 60 somatic variants for this specimen: 47 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 12, Nonsense Mutation 4, 5'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.892G>T p.E298* | Nonsense Mutation (SNP) | VAF 50/72 reads (69%) | hotspot (GDC flag); catalogued as rs201744589, CM031387, COSV52661551, COSV52761493, COSV53353479, COSV53790595; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACCS | c.1217G>A p.R406H | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.059); catalogued as rs138481594; called by mutect2, varscan2
- ACOT11 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 33/48 reads (69%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as rs150203501; called by muse, mutect2, varscan2
- ADCY2 | c.1710G>T p.W570C | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.09); catalogued as COSV100603678; called by muse, mutect2, varscan2
- AGBL5 | c.973G>A p.A325T | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.843); catalogued as COSV100549373; called by muse, mutect2
- AMPD3 | c.272C>T p.P91L (on ENST00000396553 / NM_001025389.2; = p.P100L on NM_000480.3) | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.326); catalogued as rs1432845565, COSV101158235; called by muse, mutect2, varscan2
- ARHGAP32 | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs377461049; called by muse, mutect2, varscan2
- B4GALNT3 | c.2120G>A p.G707D | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.843); catalogued as COSV56749881, COSV56752699, COSV99843470; called by muse, mutect2, varscan2
- CARNS1 | c.161C>A p.A54E | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.08); catalogued as COSV100322185; called by muse, mutect2, varscan2
- CCDC158 | c.418C>A p.Q140K | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs775899999, COSV101187346; called by muse, mutect2
- CCDC88C | c.4966G>A p.V1656I | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as rs768083419, COSV100485032; called by muse, mutect2, varscan2
- CCN1 | c.961C>T p.R321* | Nonsense Mutation (SNP) | VAF 5/71 reads (7%) | catalogued as COSV101486141; called by muse, mutect2
- CCNDBP1 | c.844G>A p.D282N | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV100281659; called by muse, varscan2
- CDH12 | c.1459C>T p.P487S | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101203210; called by muse, mutect2
- COL26A1 | c.661G>A p.D221N (on ENST00000313669 / NM_001278563.3; = p.D219N on NM_133457.4) | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.272); catalogued as COSV100561975; called by muse, mutect2
- DNAH5 | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); catalogued as rs200314274, COSV54230788; called by muse, mutect2
- FBN3 | c.6244C>T p.R2082* | Nonsense Mutation (SNP) | VAF 7/76 reads (9%) | catalogued as rs1020669396, COSV54468063, COSV99561619; called by muse, mutect2, varscan2
- FCER2 | c.836C>T p.A279V | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as COSV100689632; called by muse, mutect2
- FLNC | c.5404G>A p.V1802M | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100368556, COSV100368601; called by muse, mutect2, varscan2
- GRIN3A | c.3160G>A p.E1054K | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.114); catalogued as COSV100701730; called by muse, mutect2
- HAVCR1 | c.358G>A p.V120I | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs754029647, COSV100208529; called by muse, mutect2, varscan2
- HDAC7 | c.1034C>G p.S345C (on ENST00000427332; = p.S384C on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); catalogued as COSV99316782; called by muse, mutect2, varscan2
- ICE1 | c.1517G>A p.R506Q | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs770520751, COSV99665458; called by muse, mutect2, varscan2
- IFNW1 | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.51); catalogued as rs201715468, COSV101207639; called by muse, mutect2, varscan2
- IKZF4 | c.910C>T p.H304Y | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.346); catalogued as COSV100009291; called by muse, mutect2, varscan2
- IPO5 | c.1315C>T p.H439Y | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs769611200, COSV55152521; called by muse, mutect2, varscan2
- KCNV1 | c.1110C>G p.S370R | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.42); catalogued as COSV99819358; called by muse, mutect2, varscan2
- KIAA1549 | c.2743G>T p.A915S | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.57); PolyPhen benign (0.01); catalogued as rs780665573, COSV99651721; called by muse, mutect2, varscan2
- KLF8 | c.64A>G p.M22V | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV100808383; called by muse, mutect2, varscan2
- KNTC1 | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.386); catalogued as COSV100338693; called by muse, mutect2, varscan2
- MACF1 | c.11915A>T p.K3972M (on ENST00000372915; = p.K1905M on NM_012090.5) | Missense Mutation (SNP) | VAF 10/54 reads (19%) | catalogued as COSV99246281; called by muse, mutect2, varscan2
- MYLK2 | c.1349C>T p.S450L | Missense Mutation (SNP) | VAF 31/184 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV65659245; called by muse, mutect2, varscan2
- PAFAH1B3 | c.394C>T p.R132W | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.894); catalogued as rs200814337, COSV50662772; called by muse, mutect2, varscan2
- PAX6 | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV104384163, COSV99570728; called by muse, mutect2, varscan2
- PPP3CC | c.870C>A p.S290R | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as COSV99252404; called by muse, mutect2, varscan2
- PRAMEF14 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.432); catalogued as rs1357730808; called by muse, mutect2, varscan2
- PTPN18 | c.820G>A p.A274T | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.711); catalogued as COSV99448050; called by muse, mutect2, varscan2
- RASGRF1 | c.2036G>A p.R679H | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as rs1178189618, COSV101174712; called by muse, mutect2, varscan2
- SPATA31D1 | c.3393G>T p.K1131N | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.036); catalogued as COSV100783006; called by muse, mutect2, varscan2
- SRRM2 | c.5479C>T p.R1827W | Missense Mutation (SNP) | VAF 11/136 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs776029334, COSV100071070, COSV57070071; called by muse, mutect2
- TBX5 | c.1123C>T p.R375W | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs377532269; ClinVar: benign; called by muse, mutect2, varscan2
- TMLHE | c.847C>G p.Q283E | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.019); catalogued as COSV100545045, COSV57688814; called by muse, mutect2, varscan2
- TMPRSS15 | c.617G>A p.G206E | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99518990; called by muse, mutect2
- WDFY3 | c.8435G>C p.R2812T | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as COSV99885142; called by muse, mutect2, varscan2
- ZC3HAV1 | c.2165T>G p.F722C | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV99648980; called by muse, mutect2
- NCKAP1 | c.2279del p.D760Vfs*17 | Frame Shift Del (DEL) | VAF 16/79 reads (20%) | called by mutect2, pindel, varscan2
- TRGC1 | c.253G>T p.E85* | Nonsense Mutation (SNP) | VAF 163/242 reads (67%) | called by muse, mutect2, varscan2
- ASGR1 | c.516G>A p.G172= | Silent (SNP) | VAF 29/83 reads (35%) | catalogued as COSV99352597; called by muse, mutect2, varscan2
- BCL9L | c.3093C>T p.N1031= | Silent (SNP) | VAF 14/22 reads (64%) | catalogued as rs1400283625, COSV99419966; called by muse, mutect2
- BCLAF1 | c.858T>A p.P286= | Silent (SNP) | VAF 10/92 reads (11%) | catalogued as COSV100786872; called by muse, mutect2, varscan2
- CSMD2 | c.891C>T p.R297= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as rs143306375; called by muse, mutect2, varscan2
- DDX58 | c.174C>T p.L58= | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as COSV101153170; called by muse, mutect2, varscan2
- DLG4 | c.2142C>T p.P714= (on ENST00000399506 / NM_001321075.3; = p.P757= on NM_001365.4) | Silent (SNP) | VAF 24/77 reads (31%) | catalogued as COSV100263943; called by muse, mutect2, varscan2
- DMRT1 | c.885G>A p.P295= | Silent (SNP) | VAF 12/80 reads (15%) | catalogued as rs771988103, COSV101206605; called by muse, mutect2, varscan2
- OR2G2 | c.705C>T p.T235= | Silent (SNP) | VAF 16/280 reads (6%) | catalogued as COSV60740908; called by muse, mutect2
- SDK2 | c.2094C>T p.I698= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as rs570731428, COSV101168350; called by muse, mutect2, varscan2
- SOHLH2 | c.501G>A p.L167= | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as COSV100499497; called by muse, mutect2, varscan2
- VPS13C | c.399G>A p.G133= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs1426665842, COSV99829818; called by muse, mutect2
- ZNF358 | c.453C>T p.F151= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV99900799; called by mutect2, varscan2
- STON1 | chr2:48530026 C>A | 5'Flank (SNP) | VAF 6/18 reads (33%) | called by muse, mutect2, varscan2
